Surgical pathology report (de-identified scan), TCGA case TCGA-CL-5918, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Harvard, specimen TCGA-CL-5918-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGIC DIAGNOSIS:

A. SPECIMEN DESIGNATED "RECTUM AND SIGMOID COLON, PARTIAL COLECTOMY":
(22.0 cm):

ADENOCARCINOMA, low grade, moderately differentiated (6.0 cm in greatest dimension).

Tumor is located in rectum, forms a polypoid mass, and has a pushing border.

Tumor invades into the muscularis propria.

Proximal, distal, and radial resection margins are negative for tumor.

Invasive tumor is 18.0 cm from proximal resection margin, 3.3 cm from distal resection margin, and 0.6 cm from radial resection margin.

Lymphovascular invasion is not identified.

Extramural venous invasion is not identified.

Perineural invasion is not identified.

Peritumoral lymphoid response (including Crohn?s-like infiltrate) is mild.

Residual adenoma is absent.

Diverticulosis.

Regional lymph nodes (positive:total): 0:14.

AJCC Classification (6th edition): T3 N0 MX.

B. SPECIMEN DESIGNATED "UMBILICAL HERNIA":

Inflamed mesothelial-lined fibroadipose tissue consistent with hernia sac.

C. SPECIMEN DESIGNATED "ADDITIONAL PROXIMAL COLON, RESECTION" (12 cm):

Large bowel with diverticulosis.

There is no evidence of malignancy.

One lymph node, negative for tumor (0:1).

CLINICAL DATA:

History: [REDACTED] with rectal cancer.

Operation: Lower anterior resection + colostomy.

Operative Findings: Not provided.

Clinical Diagnosis: Rectal cancer.

TISSUE SUBMITTED:

A. Low anterior resection open + return

B. Umbilical hernia

C. Additional proximal colon

GROSS DESCRIPTION:

The specimen is received fresh, in three parts, each labeled with the patient's name and unit number.

Part A, "low anterior resection", consists of a segment of colon, consisting of rectum (22.0 cm in length x 4.9 cm in diameter) and sigmoid (7.5 cm in length x 4.5 cm in diameter). The distal stapled resection margin (4.3 cm in length) is inked black and the proximal stapled resection margin (5.5 cm in length) is inked blue. There is abundant yellow-red mesocolon and the serosa is tan-pink and smooth. The specimen is opened to exhibit a tan-pink, friable, exophytic

[page 2 of 2]
[REDACTED]

mass (6.0 x 4.2 x 1.2 cm), which exhibits rolled up borders and is located 3.3 cm from the distal margin and 18.0 cm from the proximal margin. A representative section of the tumor and of normal colon is allocated to tissue bank. On cut section, the mass is tan-pink, measures up to 1.9 cm in greatest thickness and comes to 0.6 cm from the deep margin (inked orange). The mass invades muscularis propria. The uninvolved mucosa is tan-pink and exhibits several uncomplicated diverticula. Multiple tan-pink lymph node candidates are identified ranging from 0.3 to 1.3 cm in greatest dimension.

Micro A1: Perpendicular proximal and distal margins, 2 frags, [REDACTED]
Micro A2: En face radial margin, 1 frag, [REDACTED]
Micro A3-A7: Fungating mass to include greatest depth (A3), 1 frag in each, RSS.
Micro A8: Diverticulum, 1 frag, [REDACTED]
Micro A9: 1 trisected lymph node candidate, 3 frags, [REDACTED]
Micro A10-A11: 5 lymph node candidates in each, 5 frags in each, [REDACTED]
Micro A12-A13: 4 lymph node candidates in each, 4 frags in each, [REDACTED]
Micro A14: 5 lymph node candidates, 5 frags, [REDACTED]

Part B, "umbilical hernia", consists of an irregular tan-pink smooth to focally ragged fibromembranous saccular soft tissue (3.0 x 2.0 x 1.0 cm), which is serially sectioned to exhibit a tan-pink surface. No hemorrhage or necrosis is noted.

Micro B1: 2 frags, [REDACTED].

Part C, "#3. Additional proximal colon", consists of a segment of colon (12.0 cm in length x 2.0 cm in diameter) with an opened resection margin (2.5 cm in length - inked blue) and a stapled resection margin (3.5 cm in length - inked black). The attached abundant mesocolon is yellow-red unremarkable. The serosa is tan-pink, smooth, and glistening. The specimen is opened to exhibit a tan/pink glistening mucosa with normal fold architecture. Several uncomplicated diverticula are identified. No masses or lesions are identified. A 0.3 cm tan-pink lymph node candidate is identified.

Micro C1: Perpendicular margins, 2 frags [REDACTED]
Micro C2-C3: Diverticulum, 3 frags total [REDACTED]
Micro C4: 1 lymph node candidate, 1 frag [REDACTED]

CASE NUMBER [REDACTED]

[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[REDACTED]

Source: NCI Genomic Data Commons file f749c6af-ce64-4bef-934e-aa7933ae3986 (TCGA-CL-5918.4C863C92-359E-4D16-AC0B-AA433DDB2A5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).